Surgical pathology report (de-identified scan), TCGA case TCGA-22-5481, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5481-01A (Primary Tumor).

[REDACTED] TCGA-22-5481

[REDACTED] Surgical Pathology

DIAGNOSIS:

Lung, left, pneumonectomy: Grade 4 (of 4) squamous cell carcinoma forming a 3.6 x 3.6 x 3.6 cm mass in the left lower lobe. The tumor is located 7.0 cm from the bronchial margin. The bronchial margin and visceral pleura are not involved. The uninvolved lung parenchyma is unremarkable histologically. Two (2) of 8 intrapulmonary peribronchial lymph nodes are positive for tumor, the largest of which forms a 1.7 x 1.7 x 1.7 cm adenopathy located in the fissure.

Lymph nodes, superior and inferior mediastinal, aortic and N1, excision: Multiple superior mediastinal (6 right upper paratracheal, 3 right and 5 left lower paratracheal and 4 left tracheo-bronchial), inferior mediastinal (2 left paraesophageal, 1 left inferior pulmonary ligament and 14 subcarinal), aortic (2 anterior mediastinal) and N1 (2 left interlobar) lymph nodes are negative for tumor. Necrotizing and calcified granulomas are identified in the subcarinal region. Special stains to be reported in an addendum.

Source: NCI Genomic Data Commons file 3a5dfc5e-b935-4993-a6af-221f279d9675 (TCGA-22-5481.71745674-14E0-47AC-B16C-95A18980A37D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).